Gene-level copy-number profile of tumor specimen TCGA-34-5240-01A from TCGA case TCGA-34-5240, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 73.2 years (26,735 days).
Specimen TCGA-34-5240-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.e61d159b-d96f-449f-984e-fdae8bf1899e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-34-5240-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/16a9fcdc-3a65-48e6-a051-db59c1c07be9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 2: 27,820; copy number 3: 17,033; copy number 4: 10,571; copy number 5: 316; copy number 6: 1,853; copy number 7: 531; copy number 8: 228; copy number 9: 428; copy number 10: 401; copy number 11: 628.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-34-5240-01A-01D-1439-01): tumor purity 0.64, ploidy 2.88, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:142,789–386,254, 3 genes (within-gene range 0–2): DOC2B, LINC02091, RPH3AL.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,385 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–156,007,070, 583 genes, copy number 7–9 (within-gene range 3–9) (broad region; genes not listed).
- chr3:83,384,445–84,051,419, 4 genes, copy number 6: AC023503.1, AC092825.1, SRRM1P2, AC117464.1.
- chr3:90,261,414–198,222,513, 1,803 genes, copy number 6–11 (broad region; genes not listed).
- chr9:14,475–67,726,255, 934 genes, copy number 5–6 (broad region; genes not listed).
- chr12:52,341,197–55,221,975, 158 genes, copy number 5 (broad region; genes not listed).
- chr17:21,614,487–22,706,703, 35 genes, copy number 6 (within-gene range 2–6): AC233702.1, AC233702.4, AC233702.9, KCNJ18, AC243725.1, ABBA01006766.1, NCOR1P2, UBBP4, FTLP13, LINC02002, AC138761.1, AC138761.2, FAM27E5, AC087575.1, FLJ36000, AC132825.3, AC132825.4, MTND6P35, MTCYBP13, MTRNR2L1, AC132825.2, MTND1P15, MTND2P13, AC132825.1, NMTRS-TGA3-1, MTATP6P3, MTCO3P13, AC132825.6, AC132825.7, AC132825.5, AC131055.2, AC131055.1, AC131274.3, AC131274.1, AC131274.2.
- chr18:47,390–15,330,282, 376 genes, copy number 9 (broad region; genes not listed).
- chr22:25,448,105–25,520,854, 1 gene, copy number 6 (within-gene range 4–6): CRYBB2P1.
- chr22:25,476,218–40,682,814, 491 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
